Somatic mutation profile of tumor specimen ER-B0BV-TTM1-A (aliquot ER-B0BV-TTM1-A-1-0-D-A668-34) from EXCEPTIONAL_RESPONDERS case ER-B0BV, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 62.6 years (22,862 days).
Specimen ER-B0BV-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 622f46ad-e76f-439f-9ca1-12f2909a639f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-B0BV-NB1-A (Blood Derived Normal), aliquot ER-B0BV-NB1-A-1-0-D-A75J-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/705adc3d-d9d0-4634-b410-27fe0ee0c1e8

The open-access MAF lists 201 somatic variants for this specimen: 140 protein-altering or splice-affecting, 43 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 43, Frame Shift Del 8, Nonsense Mutation 8, Intron 6, RNA 4, 3'UTR 4, Frame Shift Ins 3, 3'Flank 2, 5'UTR 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 81/163 reads (50%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 55/252 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 231/392 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 27/50 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>C p.L436P (on ENST00000383472 / NM_001366230.1; = p.L277P on NM_001010000.3) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214308156, COSV51632708, COSV51641871; called by muse, mutect2, varscan2
- ASTN2 | c.1969C>T p.R657W (on ENST00000313400 / NM_001365069.1; = p.R606W on NM_014010.5) | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs748745520, COSV100530148, COSV57761952; called by muse, mutect2, varscan2
- BCCIP | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1274845665; called by muse, mutect2, varscan2
- CACNA1I | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60813166; called by muse, mutect2, varscan2
- CAPN11 | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1187942061, COSV67237365; called by muse, mutect2
- CASP8AP2 | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99386695; called by muse, mutect2, varscan2
- CCDC88B | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1261122148; called by muse, mutect2, varscan2
- CHRM3 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs1558233542; called by muse, mutect2, varscan2
- COL6A2 | c.2591C>T p.T864M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs200488881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMMD3 | c.429G>C p.R143S | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100936513; called by muse, mutect2, varscan2
- DSP | c.4565C>G p.T1522R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV65793138, COSV65793568; called by muse, mutect2, varscan2
- ENPP2 | c.417A>T p.K139N | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV50024069; called by muse, mutect2
- FAM47C | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1215954460, COSV63726680; called by muse, mutect2, varscan2
- FAM83A | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs956961502; called by muse, mutect2, varscan2
- FAT3 | c.1648T>C p.S550P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99966236; called by muse, mutect2, varscan2
- FRMD3 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs1160597212; called by muse, mutect2, varscan2
- GGT5 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs374513263; called by muse, mutect2, varscan2
- GLIS2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.973); catalogued as rs750314209; called by muse, mutect2, varscan2
- H2AC12 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1186750684; called by muse, mutect2, varscan2
- HMCN1 | c.3235C>T p.R1079* | Nonsense Mutation (SNP) | VAF 56/109 reads (51%) | catalogued as rs768343794, COSV54908603; called by muse, mutect2, varscan2
- HMOX2 | c.605A>T p.Y202F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860764; called by muse, mutect2, varscan2
- LTBP3 | c.1975G>C p.V659L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as rs1233715148; called by mutect2, varscan2
- MRNIP | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs746108664; called by muse, varscan2
- NLRP13 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV61622568; called by muse, mutect2, varscan2
- NOS2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs760125730; called by muse, mutect2, varscan2
- NTN3 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758811567; called by muse, mutect2, varscan2
- PAH | c.853C>G p.H285D | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981447; called by muse, mutect2, varscan2
- PASK | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.219); catalogued as rs1025001208; called by muse, mutect2, varscan2
- PCDH18 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61269430; called by muse, mutect2, varscan2
- PROS1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as CM971244; called by muse, mutect2, varscan2
- RAB23 | c.480A>T p.E160D | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100443916; called by muse, mutect2, varscan2
- RPL27 | c.362+1G>C p.X121_splice | Splice Site (SNP) | VAF 38/81 reads (47%) | catalogued as rs113615221; called by muse, mutect2, varscan2
- RTL3 | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs746805876; called by muse, mutect2, varscan2
- RYR1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs773794000, COSV62098661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV61691371; called by muse, mutect2, varscan2
- SNX30 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1345366191; called by muse, mutect2
- STK4 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as rs766853466; called by muse, varscan2
- TUB | c.1256C>T p.T419M (on ENST00000299506 / NM_177972.3; = p.T474M on NM_003320.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs184649891; called by muse, mutect2, varscan2
- TUBB4A | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); catalogued as rs1196637862, COSV51163156; called by muse, mutect2, varscan2
- TULP2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55479954; called by muse, mutect2, varscan2
- TWIST1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs375138242; called by muse, mutect2, varscan2
- ZBED4 | c.3501A>G p.I1167M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1395407022; called by mutect2, varscan2
- ZFP30 | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1315879634, COSV63622729; called by muse, mutect2, varscan2
- ZNF354C | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs754570552; called by muse, mutect2, varscan2
- AARS2 | c.565_566insAATCA p.I189Kfs*5 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- ABCA6 | c.3358T>G p.F1120V | Missense Mutation (SNP) | VAF 150/567 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCF1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTG1 | c.876_895del p.L293Vfs*59 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel
- ACTN4 | c.2559G>C p.K853N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADARB2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADCY2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- AHDC1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANGPTL5 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP4E1 | c.929A>C p.H310P | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- ARHGEF2 | c.2362G>A p.G788S (on ENST00000361247 / NM_001162383.2; = p.G760S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2
- BRIX1 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CAMKK2 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CCDC6 | c.1124A>T p.H375L | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CD109 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2
- CFHR5 | c.692A>G p.E231G | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- COA8 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRACD | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSNK1D | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- CUX1 | c.639C>A p.D213E (on ENST00000292535 / NM_181552.4; = p.D224E on NM_001913.5) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CWF19L2 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CYP2U1 | c.1341G>T p.W447C | Missense Mutation (SNP) | VAF 90/329 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.9986G>A p.G3329E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DOCK4 | c.4026C>G p.Y1342* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.658C>G p.Q220E (on ENST00000450689 / NM_001142749.3; = p.Q53E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ENDOD1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.212); called by muse, mutect2
- ENPP2 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EXT1 | c.1507G>C p.A503P | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- EZH1 | c.233C>G p.P78R | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM111B | c.1394A>C p.Q465P | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GDAP1L1 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2
- GRIK1 | c.279_284dup p.R94_R95dup | In Frame Ins (INS) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- HOXD11 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- IVL | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, varscan2
- JMJD1C | c.776C>G p.T259R | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- KCNA5 | c.1629C>A p.S543R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNH6 | c.522G>C p.K174N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA0100 | c.97T>A p.W33R | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LDHAL6B | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by mutect2, varscan2
- LPCAT2 | c.500_507dup p.A170Mfs*8 | Frame Shift Ins (INS) | VAF 27/107 reads (25%) | called by mutect2, varscan2
- LRRC4B | c.1058A>C p.E353A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- LTK | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- LVRN | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAP3K14 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.14494_14497del p.E4832Kfs*21 | Frame Shift Del (DEL) | VAF 38/184 reads (21%) | called by pindel, varscan2
- MDN1 | c.11490_11506del p.H3830Qfs*11 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | called by mutect2, pindel, varscan2
- MED17 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMAB | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- MX2 | c.1994T>A p.M665K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NGB | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NGFR | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NLGN4X | c.1763C>A p.A588D | Missense Mutation (SNP) | VAF 190/247 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NPAS2 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN3 | c.1757A>T p.Y586F (on ENST00000557594 / NM_001272020.2; = p.Y1010F on NM_004796.6) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OAS1 | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- OR4K2 | c.269A>T p.K90I | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCSK7 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | called by muse, mutect2, varscan2
- PDCD11 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- PPP1R15A | c.1953_1963del p.Q651Hfs*31 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- PRDM5 | c.111del p.F38Lfs*19 | Frame Shift Del (DEL) | VAF 70/261 reads (27%) | called by mutect2, pindel, varscan2
- PTF1A | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 108/452 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, varscan2
- PTF1A | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP9 | c.1173A>T p.R391S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- RAPH1 | c.1009C>A p.L337I (on ENST00000319170 / NM_213589.3; = p.L389I on NM_203365.4) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM39 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFTN1 | c.1521G>C p.E507D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, varscan2
- RNF17 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- SARDH | c.1390T>A p.Y464N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SATL1 | c.74A>T p.D25V (on ENST00000395409; = p.D212V on NM_001012980.2) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN11A | c.710C>A p.S237* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- SEC24D | c.2531T>G p.V844G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETX | c.6935A>C p.D2312A | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SH3BP1 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SLC30A6 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC3A2 | c.547T>A p.W183R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNX31 | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SOWAHB | c.1247del p.P416Rfs*67 | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by pindel, varscan2
- SOX6 | c.1628G>A p.R543K (on ENST00000528429 / NM_001145819.2; = p.R516K on NM_017508.3) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SPON1 | c.332C>G p.A111G | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TAS1R2 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TCEA1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TGFBR1 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIGD7 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); called by muse, mutect2
- TMEM132C | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TRMT1 | c.1444T>A p.C482S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TTN | c.17643_17649del p.P5882Lfs*5 (on ENST00000591111; = p.P4955Lfs*5 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- UBE3A | c.1502_1507del p.M501_Y502del | In Frame Del (DEL) | VAF 34/151 reads (23%) | called by mutect2, pindel, varscan2
- UNC93A | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS72 | c.1063del p.R355Efs*46 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | called by mutect2, pindel, varscan2
- ZNF502 | c.1171A>T p.S391C | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF780A | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ZSCAN29 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ADCY1 | c.1440T>C p.H480= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13596A>G p.P4532= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs750915198; called by muse, mutect2, varscan2
- AMPD3 | c.1635C>T p.D545= (on ENST00000396553 / NM_001025389.2; = p.D554= on NM_000480.3) | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs376688327; called by muse, mutect2, varscan2
- AP4E1 | c.930C>T p.H310= | Silent (SNP) | VAF 18/264 reads (7%) | called by muse, mutect2
- CCDC105 | c.156C>T p.S52= | Silent (SNP) | VAF 66/124 reads (53%) | called by muse, mutect2, varscan2
- CCDC93 | c.984A>G p.Q328= | Silent (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2, varscan2
- CDR2L | c.1209G>C p.G403= | Silent (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- CEACAM6 | c.624C>T p.N208= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs979580658, COSV52267852; called by muse, mutect2
- CIPC | c.312C>T p.S104= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- CORIN | c.1971T>C p.D657= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs768836851; called by muse, mutect2, varscan2
- CRTC2 | c.1401T>G p.T467= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- DNAH10 | c.13341T>A p.A4447= (on ENST00000409039; = p.A4386= on NM_207437.3) | Silent (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- EYS | c.6690C>T p.S2230= | Silent (SNP) | VAF 58/1185 reads (5%) | catalogued as COSV65499851; called by muse, mutect2
- FARSA | c.1215C>T p.F405= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs776938985; called by muse, mutect2, varscan2
- FYB2 | c.1644C>T p.F548= | Silent (SNP) | VAF 65/214 reads (30%) | called by muse, mutect2, varscan2
- GLT1D1 | c.876T>A p.P292= (on ENST00000442111 / NM_001366889.1; = p.P212= on NM_144669.3) | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- HFE | c.69C>G p.R23= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- HRNR | c.327A>G p.Q109= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- IGLV2-33 | c.147G>A p.G49= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs111539474; called by muse, varscan2
- IZUMO1R | c.132T>C p.Y44= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- KNTC1 | c.4203C>G p.L1401= | Silent (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- MAMLD1 | c.510G>A p.P170= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as rs1557406267, COSV99475456; called by muse, mutect2, varscan2
- MYO1A | c.1029C>T p.D343= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs934081266; called by muse, mutect2, varscan2
- NAV1 | c.3766C>T p.L1256= | Silent (SNP) | VAF 105/167 reads (63%) | called by muse, mutect2, varscan2
- NEB | c.19578T>A p.I6526= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- NXPH2 | c.132C>G p.V44= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV55642944; called by muse, mutect2, varscan2
- OBSL1 | c.2100C>T p.P700= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs372718496; called by muse, mutect2, varscan2
- OR4D5 | c.192C>A p.G64= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1462390384, COSV58309343; called by muse, mutect2, varscan2
- PATJ | c.3351C>T p.N1117= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs746999831; called by muse, mutect2, varscan2
- PAXIP1 | c.1434A>G p.P478= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1428576143; called by muse, mutect2, varscan2
- PITX2 | c.265C>A p.R89= (on ENST00000354925 / NM_001204397.1; = p.R96= on NM_000325.6) | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as CM051958, COSV60740451; called by muse, mutect2, varscan2
- PLCB1 | c.3528C>T p.D1176= | Silent (SNP) | VAF 90/198 reads (45%) | called by muse, mutect2, varscan2
- PWWP3A | c.1461C>T p.G487= (on ENST00000627377; = p.G486= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1235686438, COSV100261946; called by muse, mutect2, varscan2
- RAB44 | c.2613G>T p.R871= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1374G>A p.P458= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs773163521; called by muse, mutect2, varscan2
- REM2 | c.504T>C p.Y168= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- SMAP1 | c.1023C>T p.G341= (on ENST00000370455 / NM_001044305.3; = p.G314= on NM_021940.5) | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- SPTB | c.1885C>A p.R629= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV67629686; called by muse, mutect2, varscan2
- TANGO2 | c.438C>T p.I146= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs376299828; called by muse, mutect2, varscan2
- TMEM160 | c.456C>T p.A152= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1198157369; called by muse, mutect2, varscan2
- TRPM6 | c.5313C>G p.S1771= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.28632A>G p.Q9544= (on ENST00000591111; = p.Q8617= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- UNC45A | c.2067C>T p.G689= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs200029222; called by muse, mutect2, varscan2
- AC244258.1 | n.440_479del | RNA (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- AL353804.7 | chrX:73852402 T>G | 3'Flank (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- ANKRD34C | c.*2590A>T | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- DIS3 | c.228+257T>G | Intron (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- FPR2 | c.*230G>C | 3'UTR (SNP) | VAF 69/217 reads (32%) | called by muse, mutect2, varscan2
- FUT9 | c.*9448T>A | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- FZD7 | c.*1560del | 3'UTR (DEL) | VAF 54/188 reads (29%) | called by mutect2, varscan2
- GRHPR | c.734+430G>A | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- KRT17P1 | n.810T>C | RNA (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- LCLAT1 | c.743-34004C>T | Intron (SNP) | VAF 11/166 reads (7%) | catalogued as rs1200843368, COSV58377085; called by muse, mutect2
- MFRP | chr11:119344964 C>A | 5'Flank (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- OR2W5 | n.530C>G | RNA (SNP) | VAF 6/54 reads (11%) | catalogued as rs767958235; called by mutect2, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 8/46 reads (17%) | catalogued as rs769032953; called by mutect2, varscan2
- PKD2 | c.1717-19T>A | Intron (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- RPE | c.342+114A>G | Intron (SNP) | VAF 5/56 reads (9%) | catalogued as rs1195360425, COSV63278102; called by muse, mutect2
- TP73-AS1 | n.1339G>A | RNA (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- TWIST1 | c.-80C>T | 5'UTR (SNP) | VAF 37/140 reads (26%) | catalogued as rs2522205; called by muse, mutect2, varscan2
- ZSWIM1 | c.*348+154C>T | Intron (SNP) | VAF 6/69 reads (9%) | catalogued as rs1424154475; called by muse, mutect2
